Somatic mutation profile of tumor specimen MBCProject_1819_T1_WES (aliquot MBCProject_1819_T1_WES_1) from CMI case MBCProject_1819, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.2 years (16,515 days).
Specimen MBCProject_1819_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa13331d-66bc-410a-9253-928a4929b1ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1819_SALIVA (Saliva), aliquot MBCProject_1819_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53d3cbbb-f797-414f-828f-677d6b9c2613

The open-access MAF lists 80 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Intron 5, 3'UTR 1, RNA 1, Frame Shift Del 1, Splice Region 1, 5'Flank 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs762790030; called by muse, mutect2, varscan2
- AHNAK2 | c.10642G>A p.E3548K | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs751727406; called by muse, mutect2
- ATP2B1 | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.287); catalogued as COSV99666302; called by muse, mutect2
- C2orf73 | c.560del p.P187Lfs*8 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as COSV58312064; called by mutect2, pindel
- CASS4 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 25/498 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV64385846; called by muse, mutect2
- CAST | c.2075C>T p.A692V (on ENST00000341926; = p.A775V on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs767408102; called by muse, mutect2, varscan2
- CEP70 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV53876087; called by muse, mutect2
- CSMD2 | c.8468C>T p.S2823F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV53948476; called by muse, mutect2
- DSG2 | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs375422019, COSV55199493; called by muse, mutect2, varscan2
- GAS1 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.859); catalogued as rs745783505; called by muse, mutect2, varscan2
- HECTD1 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs773261934; called by muse, mutect2, varscan2
- HNRNPCL1 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1407469026; called by muse, mutect2, varscan2
- HNRNPH1 | c.1208-4A>G | Splice Region (SNP) | VAF 43/301 reads (14%) | catalogued as rs748536618; called by muse, mutect2, varscan2
- KMT5B | c.1461T>A p.N487K | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV58563599; called by muse, mutect2, varscan2
- LTBP4 | c.4217G>A p.R1406H (on ENST00000308370 / NM_001042544.1; = p.R1369H on NM_003573.2) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs757090322, COSV52592272; called by muse, mutect2
- MUC17 | c.3245C>G p.S1082C | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60307443; called by muse, mutect2, varscan2
- MYLK | c.3617C>T p.P1206L | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as rs1222125596; called by muse, mutect2, varscan2
- NCOA3 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.119); catalogued as rs955693886; called by muse, mutect2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 177/448 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- SI | c.3134C>T p.P1045L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430639752; called by muse, mutect2, varscan2
- TIMM50 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760304945, COSV58680278; called by muse, mutect2, varscan2
- TUBB8B | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1247629890; called by muse, varscan2
- UNC5D | c.2203C>G p.L735V | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV54772013; called by muse, mutect2, varscan2
- VAV2 | c.846C>G p.I282M (on ENST00000371850 / NM_001134398.2; = p.I277M on NM_003371.4) | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1376631871; called by muse, mutect2, varscan2
- ACTB | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 101/496 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ADAM20 | c.1213T>G p.F405V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADAM9 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 450/503 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CD82 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 77/314 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CERS3 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CPNE5 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CT55 | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAM189B | c.1750G>A p.G584S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- FAT1 | c.4018A>G p.R1340G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMD8 | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GOLT1A | c.301T>A p.F101I | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2
- GOSR1 | c.749A>T p.H250L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- KANK1 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- KANK3 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- KRTAP10-10 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- KRTAP21-1 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- LARGE2 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP4 | c.2726C>A p.A909D | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LTBP3 | c.1897A>G p.M633V | Missense Mutation (SNP) | VAF 87/422 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MICAL2 | c.2263G>T p.G755C | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MYO6 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- N4BP2 | c.5128G>C p.E1710Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NASP | c.1462G>C p.D488H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- PFAS | c.1456C>G p.R486G | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN2A | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- SH3GLB1 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLX4 | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TP53 | c.731dup p.G245Rfs*19 | Frame Shift Ins (INS) | VAF 76/223 reads (34%) | called by mutect2, pindel, varscan2
- USO1 | c.2769G>T p.L923F | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- WDR25 | c.1254C>G p.I418M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ABCG4 | c.1272C>A p.T424= | Silent (SNP) | VAF 40/231 reads (17%) | called by muse, mutect2, varscan2
- AKR1B1 | c.459G>C p.L153= | Silent (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2, varscan2
- AKR1B15 | c.417C>T p.H139= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs1464307730; called by muse, mutect2, varscan2
- DCAF13 | c.1338A>G p.*446= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs763601552; called by muse, mutect2, varscan2
- HOXB3 | c.408G>A p.S136= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, varscan2
- LRRC27 | c.1521G>A p.P507= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs759756403; called by muse, mutect2, varscan2
- NKD2 | c.384C>T p.F128= | Silent (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- NLRP12 | c.2710C>T p.L904= | Silent (SNP) | VAF 22/287 reads (8%) | catalogued as rs1420357536; called by muse, mutect2
- OR4S2 | c.637C>T p.L213= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- PAF1 | c.726T>A p.S242= | Silent (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- PIEZO1 | c.3903C>T p.V1301= | Silent (SNP) | VAF 23/169 reads (14%) | catalogued as rs1362108393; called by muse, mutect2, varscan2
- RPLP2 | c.282G>A p.K94= | Silent (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- SCN10A | c.4588T>C p.L1530= | Silent (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- SPATA16 | c.1467C>T p.P489= | Silent (SNP) | VAF 109/192 reads (57%) | catalogued as rs755176371; called by muse, mutect2, varscan2
- TTN | c.22302T>C p.T7434= (on ENST00000591111; = p.T6507= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.417C>A p.L139= | Silent (SNP) | VAF 23/215 reads (11%) | called by muse, mutect2, varscan2
- ZXDA | c.852G>A p.L284= | Silent (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- AHI1 | chr6:135497837 C>G | 5'Flank (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- AK2 | c.*1208T>C | 3'UTR (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- C2CD6 | c.1581+2094G>C | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as rs1462381977; called by muse, varscan2
- CCNQP1 | n.54C>G | RNA (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2
- IRF7 | c.719-22C>A | Intron (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- LUC7L | c.61+923A>G | Intron (SNP) | VAF 50/138 reads (36%) | called by muse, varscan2
- SLC25A36 | c.385+3731G>C | Intron (SNP) | VAF 23/165 reads (14%) | called by muse, varscan2
- TRIM26 | c.788+31C>T | Intron (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
